Somatic mutation profile of tumor specimen TCGA-13-1505-01A (aliquot TCGA-13-1505-01A-01D-0472-01) from TCGA case TCGA-13-1505, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.6 years (23,238 days).
Specimen TCGA-13-1505-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b589a197-7569-4ed5-893a-264ab15ca687.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1505-10A (Blood Derived Normal), aliquot TCGA-13-1505-10A-01D-0472-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9aed54f1-d3f9-4d60-90ab-48a808eef571

The open-access MAF lists 77 somatic variants for this specimen: 57 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 18, Nonsense Mutation 4, Frame Shift Del 4, Intron 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP35 | c.3433C>T p.R1145* | Nonsense Mutation (SNP) | VAF 21/109 reads (19%) | catalogued as COSV68329138; called by muse, mutect2, varscan2
- ARL15 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV72291534; called by muse, mutect2
- ARMCX2 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.624); catalogued as COSV57530754; called by muse, mutect2, varscan2
- B4GALT6 | c.624C>G p.F208L | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0.019); catalogued as COSV99380086; called by muse, mutect2
- C3orf20 | c.2380G>T p.G794W | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53787361; called by muse, mutect2, varscan2
- CADPS | c.586A>G p.M196V | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.824); catalogued as rs778806598, COSV99338717; called by muse, mutect2, varscan2
- CD82 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1339483186, COSV57036117; called by muse, mutect2, varscan2
- CEACAM5 | c.1646T>A p.L549Q | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV55753544; called by muse, mutect2
- CEP164 | c.4355A>C p.H1452P | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV54043863; called by muse, mutect2
- CNOT9 | c.264C>A p.N88K | Missense Mutation (SNP) | VAF 71/476 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55300925; called by muse, varscan2
- CR1 | c.5395A>G p.I1799V | Missense Mutation (SNP) | VAF 99/279 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV65460538; called by muse, mutect2, varscan2
- CRISPLD1 | c.728-2A>T p.X243_splice | Splice Site (SNP) | VAF 6/122 reads (5%) | catalogued as COSV100082081; called by muse, mutect2
- CROCC | c.267G>C p.E89D | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65013678; called by muse, mutect2, varscan2
- EI24 | c.314T>C p.I105T | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1262939623, COSV54020281; called by muse, mutect2, varscan2
- EIF4G2 | c.2208A>C p.E736D | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.019); catalogued as COSV60598326; called by muse, mutect2, varscan2
- ELF4 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 38/311 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1220135107, COSV57453833; called by muse, mutect2, varscan2
- EXOC3L4 | c.1947G>C p.E649D | Missense Mutation (SNP) | VAF 116/366 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV66295774; called by muse, mutect2, varscan2
- FAAP100 | c.2183del p.L728Rfs*19 | Frame Shift Del (DEL) | VAF 10/13 reads (77%) | catalogued as COSV59886657; called by mutect2, varscan2
- FHOD1 | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV50764451; called by muse, mutect2, varscan2
- FMR1 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 47/248 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54424168, COSV54425872; called by muse, mutect2, varscan2
- FREM2 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs761616009, COSV54844820; called by muse, mutect2, varscan2
- GAB3 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782361857, COSV65820308; called by muse, mutect2, varscan2
- HUNK | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.556); catalogued as COSV54226978; called by muse, mutect2, varscan2
- IQGAP3 | c.2542C>T p.H848Y | Missense Mutation (SNP) | VAF 15/299 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV100752172; called by muse, mutect2
- ITK | c.781G>C p.A261P | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV68435396; called by muse, mutect2, varscan2
- KANK1 | c.1886G>A p.G629D | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV63213943; called by muse, mutect2, varscan2
- KIR3DL3 | c.429A>T p.Q143H | Missense Mutation (SNP) | VAF 92/959 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV99399951; called by muse, mutect2
- KLHL25 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.511); catalogued as COSV61995773; called by muse, mutect2, varscan2
- LRFN5 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs1486862715, COSV53243274; called by muse, mutect2
- MC2R | c.196T>A p.L66M | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59619363; called by muse, mutect2, varscan2
- MED13L | c.1614G>T p.K538N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.154); catalogued as COSV99929040; called by muse, mutect2, varscan2
- MIPOL1 | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100539023; called by mutect2, varscan2
- MYADM | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV61240389; called by muse, mutect2, varscan2
- MYCBPAP | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs138709333; called by muse, mutect2, varscan2
- NME8 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV52253326; called by muse, mutect2, varscan2
- OR5D13 | c.8C>A p.A3E | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); catalogued as COSV62334610; called by muse, mutect2, varscan2
- OR5M11 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 54/312 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1213848841, COSV73141712; called by muse, mutect2, varscan2
- PARD6A | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as COSV54669113; called by muse, mutect2, varscan2
- PLD2 | c.1613_1614del p.M538Tfs*102 | Frame Shift Del (DEL) | VAF 167/253 reads (66%) | catalogued as COSV54007787; called by mutect2, pindel, varscan2
- PLEKHH3 | c.190C>G p.P64A | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV53190396; called by muse, mutect2, varscan2
- PPP1R3A | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99493100; called by muse, mutect2, varscan2
- PTPRH | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 40/281 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV54744904, COSV54747853; called by muse, mutect2, varscan2
- PYY | c.266C>A p.S89* | Nonsense Mutation (SNP) | VAF 12/103 reads (12%) | catalogued as COSV100778960; called by muse, mutect2, varscan2
- PYY | c.265T>C p.S89P | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV100778962; called by muse, mutect2, varscan2
- RSRC2 | c.67A>T p.K23* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100063272, COSV59206155; called by muse, mutect2, varscan2
- SLC17A8 | c.813G>T p.E271D | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV60125282; called by muse, mutect2, varscan2
- SRSF8 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 68/286 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.633); catalogued as COSV71665575; called by muse, mutect2, varscan2
- TP53 | c.225del p.A76Hfs*47 | Frame Shift Del (DEL) | VAF 575/856 reads (67%) | catalogued as COSV53328406; called by mutect2, pindel, varscan2
- TPH2 | c.947C>G p.T316R | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV61593139; called by muse, mutect2, varscan2
- TRPC4 | c.865C>A p.L289I | Missense Mutation (SNP) | VAF 11/337 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100157016; called by muse, mutect2
- TSPAN32 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1034351419, COSV51719445, COSV99478235; called by muse, mutect2, varscan2
- TTN | c.98857C>T p.R32953C (on ENST00000591111; = p.R25529C on NM_003319.4) | Missense Mutation (SNP) | VAF 13/132 reads (10%) | PolyPhen probably damaging (0.998); catalogued as rs879240376, COSV60202286; called by muse, mutect2, varscan2
- TTN | c.55477T>A p.S18493T (on ENST00000591111; = p.S11069T on NM_003319.4) | Missense Mutation (SNP) | VAF 72/653 reads (11%) | PolyPhen benign (0.005); catalogued as rs904878126, COSV60202298; called by muse, mutect2, varscan2
- UPF3B | c.1102C>T p.R368W (on ENST00000276201 / NM_080632.3; = p.R355W on NM_023010.3) | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.858); catalogued as rs374676402, COSV52230481; called by muse, mutect2, varscan2
- GAS2L2 | c.704T>A p.V235E | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV3-35 | c.101G>C p.G34A | Missense Mutation (SNP) | VAF 157/1447 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- LAYN | c.166del p.H56Mfs*7 (on ENST00000375615 / NM_001258390.1; = p.H48Mfs*7 on NM_178834.5) | Frame Shift Del (DEL) | VAF 13/119 reads (11%) | called by mutect2, pindel, varscan2
- ADGRF3 | c.2430C>T p.A810= (on ENST00000311519 / NM_001145168.1; = p.A611= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs754989392, COSV61049348; called by muse, mutect2, varscan2
- ATP2A1 | c.1641G>A p.A547= | Silent (SNP) | VAF 37/222 reads (17%) | catalogued as rs1387468030, COSV63921718; called by muse, mutect2, varscan2
- C1QBP | c.375C>G p.A125= | Silent (SNP) | VAF 48/522 reads (9%) | catalogued as COSV56580025; called by muse, mutect2
- CADPS | c.585C>T p.R195= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV99338720; called by muse, mutect2, varscan2
- COL22A1 | c.3135G>T p.G1045= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV57348555; called by muse, mutect2, varscan2
- FAM90A1 | c.21C>G p.P7= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV56713584; called by muse, mutect2
- FAT4 | c.3411T>C p.Y1137= | Silent (SNP) | VAF 27/154 reads (18%) | catalogued as COSV67893930; called by muse, mutect2, varscan2
- FAT4 | c.10245C>A p.I3415= | Silent (SNP) | VAF 36/243 reads (15%) | catalogued as COSV58698292; called by muse, mutect2, varscan2
- GRIA1 | c.1275C>T p.N425= | Silent (SNP) | VAF 83/221 reads (38%) | catalogued as rs142814149; called by muse, mutect2, varscan2
- HTT | c.5850C>T p.S1950= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs201305332; called by muse, mutect2, varscan2
- L1CAM | c.2691C>A p.A897= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV62829106; called by muse, mutect2, varscan2
- MUC16 | c.12921G>A p.Q4307= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as COSV101200118; called by muse, mutect2
- PDGFRA | c.3108G>A p.K1036= | Silent (SNP) | VAF 15/451 reads (3%) | catalogued as COSV99956744; called by muse, mutect2
- PRDM1 | c.1377C>A p.P459= | Silent (SNP) | VAF 13/183 reads (7%) | catalogued as COSV100958824; called by muse, mutect2
- RILP | c.1191C>T p.A397= | Silent (SNP) | VAF 54/72 reads (75%) | catalogued as rs368151611, COSV53960020; called by muse, mutect2, varscan2
- RNF112 | c.1035G>T p.V345= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV71327091; called by muse, mutect2, varscan2
- TSPAN32 | c.912C>G p.G304= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99478240; called by muse, varscan2
- ZNF41 | c.2082T>C p.G694= | Silent (SNP) | VAF 38/247 reads (15%) | catalogued as rs147527536, COSV57444295; called by muse, mutect2, varscan2
- SSX6P | n.74C>T | RNA (SNP) | VAF 200/577 reads (35%) | catalogued as rs150874433; called by muse, mutect2, varscan2
- TTN | c.10361-3808_10361-3806dup | Intron (INS) | VAF 34/215 reads (16%) | called by mutect2, varscan2
